TCGA case TCGA-AN-A0XV — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac18b3a3-8d52-4e35-8625-673171a7fd92

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.8 years (24,779 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 16; Micrometastasis present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 162 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Positive; Staining intensity value: 2+; Test value range: 60-69%.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 1+; Test value range: 30-39%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AN-A0XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-AN-A0XV-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-AN-A0XV-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AN-A0XV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Er positivity method: dextran coated charcoal; Pr positivity define method: dextran coated charcoal; Axillary staging method: Axillary lymph node dissection alone; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Her2 IHC score: 2+; Method initial path diagnosis: Tumor resection; Pr positivity scale other: 90 H; Er positivity scale other: 270 H; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 162 days; disease-specific survival: no event (censored), 162 days; disease-free interval: no event (censored), 162 days; progression-free interval: no event (censored), 162 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AN-A0XV-01A-11D-A107-01): tumor purity 0.52, ploidy 2, whole-genome doublings 0.
